MMRF case MMRF_1630 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7cbe1fe9-2d1d-4771-ac2b-c8da10e9d27f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.2 years (21,613 days); ISS stage: II; Days to last known disease status: 1,211 days (3.3 years); Days to last follow up: 1,211 days (3.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 867 days (2.4 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 172 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 174 days; Days to treatment end: 174 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 252 days; Days to treatment end: 371 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 252 days; Days to treatment end: 658 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 371 days (1.0 years); Days to treatment end: 658 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 867 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 0): M Protein 5.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.224 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.5 mg/dL; Immunoglobulin G 70.7 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 30 g/L; Total Protein 10.4 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 84 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.164 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.759 mg/dL; Immunoglobulin G 7.28 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 4.35 mmol/L.
- Day 171 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.136 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.155 mg/dL; Immunoglobulin G 4.36 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 280 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.135 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.767 mg/dL; Immunoglobulin G 5.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 47 g/L; Total Protein 6.4 g/dL; Glucose 4.84 mmol/L.
- Day 371 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.611 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.647 mg/dL; Immunoglobulin G 4.09 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 4.35 mmol/L.
- Day 455 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.115 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.515 mg/dL; Immunoglobulin G 3.18 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.54 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 539 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 2.8 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.51 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 5.9 g/dL; Glucose 4.62 mmol/L.
- Day 623 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.549 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.58 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 5.8 g/dL; Glucose 3.91 mmol/L.
- Day 714 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.208 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.182 mg/dL; Immunoglobulin G 4.44 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.29 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 4.73 mmol/L.
- Day 812 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.662 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.713 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 896 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.846 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.324 mg/dL; Immunoglobulin G 8.84 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.11 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.46 mmol/L.
- Day 987 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.344 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.84 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 1,099 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.943 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.369 mg/dL; Immunoglobulin G 7.26 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.71 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 1,211 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 8.54 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.83 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day 0: Weight: 83 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1630_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1630_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
